Somatic mutation profile of tumor specimen TCGA-WP-A9GB-01A (aliquot TCGA-WP-A9GB-01A-11D-A37C-09) from TCGA case TCGA-WP-A9GB, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Myometrium.
Specimen TCGA-WP-A9GB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c78a87d0-fda4-42d5-9f19-07923bc1aeb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WP-A9GB-10A (Blood Derived Normal), aliquot TCGA-WP-A9GB-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3711b80-c240-410a-8938-341def8a642d

The open-access MAF lists 135 somatic variants for this specimen: 109 protein-altering or splice-affecting, 22 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 22, Frame Shift Del 8, Nonsense Mutation 7, Intron 2, 3'UTR 1, 5'Flank 1, In Frame Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 67/67 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.11393G>T p.S3798I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV101447199; called by muse, mutect2, varscan2
- ABCB9 | c.714C>A p.G238= | Splice Region (SNP) | VAF 3/47 reads (6%) | catalogued as COSV99757881; called by muse, mutect2
- AC008397.2 | c.1453C>T p.R485* | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as rs1449297362, COSV99442251; called by muse, mutect2, varscan2
- ACAT1 | c.608A>G p.K203R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV99759404; called by muse, mutect2, varscan2
- ADGRB1 | c.1332C>A p.N444K | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (1); PolyPhen possibly damaging (0.492); catalogued as COSV100030311; called by muse, mutect2, varscan2
- AHNAK | c.4542A>T p.K1514N | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99949484; called by muse, mutect2, varscan2
- ATR | c.1550T>C p.F517S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV100638570; called by muse, mutect2, varscan2
- BAZ1A | c.3766G>C p.E1256Q | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.382); catalogued as COSV100701212; called by muse, mutect2, varscan2
- BRIP1 | c.3232A>G p.K1078E | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.059); catalogued as COSV99370989; called by muse, mutect2, varscan2
- CALML5 | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 25/25 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV66702589; called by muse, mutect2, varscan2
- CCT8L2 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100743107, COSV63461681; called by muse, mutect2, varscan2
- CFH | c.1745G>T p.R582L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as CM134084, COSV66408057; called by muse, mutect2, varscan2
- CHMP4B | c.124T>A p.F42I | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV99460037; called by muse, mutect2, varscan2
- CHRD | c.1240G>C p.D414H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99200770, COSV99200904; called by muse, mutect2, varscan2
- CHRNA3 | c.1286A>G p.D429G | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100468620; called by muse, mutect2, varscan2
- CLTC | c.1782A>C p.Q594H | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99292856; called by muse, mutect2, varscan2
- CLTCL1 | c.3836A>G p.H1279R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV99595848; called by muse, mutect2, varscan2
- CRNN | c.790C>G p.Q264E | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV99664396; called by muse, mutect2, varscan2
- CSPG5 | c.1049T>A p.L350* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV99274150; called by muse, mutect2, varscan2
- CTBP1 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745938565, COSV99337323; called by muse, mutect2, varscan2
- CUBN | c.5783G>A p.G1928D | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100913490; called by muse, mutect2, varscan2
- CYP2A13 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); catalogued as COSV100387003; called by muse, mutect2, varscan2
- DGKK | c.431A>T p.E144V | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV101053206; called by muse, mutect2, varscan2
- DTD2 | c.494T>C p.L165S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV60428577; called by muse, mutect2, varscan2
- DTX4 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs376061897; called by muse, mutect2, varscan2
- EFCAB13 | c.2842C>T p.Q948* | Nonsense Mutation (SNP) | VAF 32/64 reads (50%) | catalogued as COSV100516924; called by muse, mutect2, varscan2
- ELFN2 | c.2283C>A p.Y761* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as COSV101297637; called by muse, mutect2, varscan2
- ELOA3 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 42/608 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs748997785, COSV55293762; called by muse, mutect2
- FAM131B | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1226317504, COSV101281795, COSV101281875; called by muse, mutect2, varscan2
- FTCD | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99385431; called by muse, mutect2, varscan2
- FZD3 | c.1351A>G p.T451A | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.403); catalogued as COSV99528380; called by muse, mutect2, varscan2
- GADL1 | c.1232G>C p.R411P | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV56974430, COSV56976129, COSV99245029; called by muse, mutect2, varscan2
- GREB1 | c.4296A>G p.I1432M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV99303756; called by muse, mutect2
- HDAC3 | c.125A>G p.Y42C | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1175518468, COSV99781518; called by muse, mutect2, varscan2
- HECTD2 | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as COSV99978955; called by muse, mutect2, varscan2
- HIVEP3 | c.3490T>C p.S1164P | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs187400091, COSV56013013; called by muse, mutect2, varscan2
- HSD3B1 | c.980T>G p.F327C | Missense Mutation (SNP) | VAF 19/20 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99348085; called by muse, mutect2
- HYDIN | c.4772+2T>A p.X1591_splice | Splice Site (SNP) | VAF 44/176 reads (25%) | catalogued as COSV59264833, COSV99993644; called by muse, varscan2
- ICA1 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 13/26 reads (50%) | catalogued as rs1216728776, COSV55583687; called by muse, mutect2, varscan2
- IKZF3 | c.713G>A p.S238N | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99500148; called by muse, mutect2, varscan2
- IL26 | c.353T>G p.L118W | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV99970968; called by muse, mutect2, varscan2
- KDM5B | c.3596T>A p.F1199Y | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV99351379; called by muse, mutect2, varscan2
- KDR | c.10A>G p.K4E | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99818578; called by muse, mutect2, varscan2
- KIAA1217 | c.5180C>T p.P1727L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100287248, COSV56822414; called by muse, mutect2, varscan2
- KIF13A | c.2317T>A p.Y773N | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV99438039; called by muse, mutect2, varscan2
- LONP1 | c.1070A>C p.K357T | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as COSV100638738; called by muse, mutect2, varscan2
- LRRIQ3 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs779874900, COSV100599440; called by muse, mutect2, varscan2
- MBNL3 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV100898519; called by muse, mutect2
- MDN1 | c.4651C>T p.R1551C | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs543829019, COSV101020944; called by muse, mutect2, varscan2
- MSANTD2 | c.82C>G p.P28A | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.037); catalogued as COSV99515952; called by muse, mutect2, varscan2
- MYOM2 | c.1631A>T p.Y544F | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100038346; called by muse, mutect2, varscan2
- NBEAL2 | c.5935C>T p.R1979W | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771025246, COSV99437512; called by muse, mutect2, varscan2
- NLRP5 | c.2395A>G p.K799E | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1425134187, COSV101173870; called by muse, mutect2, varscan2
- NPR2 | c.950C>A p.A317D | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV100709714; called by muse, mutect2, varscan2
- OR1N1 | c.190C>A p.L64M | Missense Mutation (SNP) | VAF 31/31 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100509824, COSV59196420; called by muse, mutect2, varscan2
- OR2M3 | c.408G>C p.M136I | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV101513515; called by muse, mutect2, varscan2
- OR4A5 | c.293A>C p.Q98P | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV100157292; called by muse, mutect2, varscan2
- OR8D1 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV100766675; called by muse, mutect2, varscan2
- OTOP3 | c.633G>T p.R211S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV100173043; called by muse, mutect2, varscan2
- P2RY6 | c.492C>G p.I164M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.077); catalogued as COSV100573993, COSV62936899; called by muse, mutect2, varscan2
- PARP14 | c.3233A>C p.K1078T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV101506345; called by muse, varscan2
- PDZK1 | c.1079T>C p.L360P | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1464412940, COSV100572533; called by muse, mutect2, varscan2
- PHLDB2 | c.1837G>T p.D613Y | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV101208688; called by muse, mutect2, varscan2
- PLXNA1 | c.830T>A p.F277Y | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV99304040; called by muse, mutect2, varscan2
- PRKD3 | c.1199T>A p.L400Q | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52220915; called by muse, mutect2, varscan2
- PSD4 | c.209T>A p.V70E | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.07); catalogued as COSV99831461; called by muse, mutect2, varscan2
- PTPRF | c.515T>C p.F172S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.898); catalogued as COSV100741221; called by muse, mutect2
- RLIM | c.956T>A p.I319K | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100223311; called by muse, mutect2, varscan2
- RPAP3 | c.1438T>G p.S480A | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV99139547; called by muse, mutect2, varscan2
- RPL36 | c.169G>C p.A57P | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as COSV100028711; called by muse, mutect2, varscan2
- SEC14L1 | c.1717C>G p.P573A | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV101171178; called by muse, mutect2, varscan2
- SEC24D | c.1732T>C p.F578L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.086); catalogued as COSV99756764; called by muse, mutect2, varscan2
- SLC24A4 | c.1629G>T p.M543I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.163); catalogued as COSV100106075; called by muse, mutect2, varscan2
- SMG1 | c.5779C>G p.Q1927E | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.9); catalogued as COSV101246782; called by muse, mutect2, varscan2
- SPRY4 | c.58C>T p.P20S (on ENST00000434127 / NM_001127496.3; = p.P43S on NM_030964.4) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100702233; called by muse, mutect2
- STOX1 | c.433C>A p.L145I | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100058237; called by muse, mutect2
- STYXL2 | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761274494, COSV99609855; called by muse, mutect2, varscan2
- SYCP3 | c.573G>C p.K191N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV57149079; called by muse, mutect2, varscan2
- SYNE1 | c.12887A>G p.K4296R (on ENST00000367255 / NM_182961.4; = p.K4225R on NM_033071.3) | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.119); catalogued as COSV99577682; called by muse, mutect2, varscan2
- SYT16 | c.1894A>G p.K632E | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.342); catalogued as COSV101413684; called by muse, mutect2, varscan2
- TAFA5 | c.170C>T p.P57L (on ENST00000402357 / NM_001082967.3; = p.P50L on NM_015381.7) | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100386557; called by muse, mutect2, varscan2
- TELO2 | c.419A>T p.Q140L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.034); catalogued as COSV99248701; called by muse, mutect2, varscan2
- TENM2 | c.3551A>G p.H1184R (on ENST00000518659 / NM_001122679.2; = p.H952R on NM_001080428.3) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101319399; called by muse, mutect2, varscan2
- TET3 | c.3185C>T p.P1062L | Missense Mutation (SNP) | VAF 21/22 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101328102; called by muse, mutect2, varscan2
- TEX2 | c.113T>C p.F38S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99367472; called by muse, mutect2, varscan2
- TMCC2 | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.222); catalogued as COSV100788331; called by muse, mutect2, varscan2
- TMPRSS15 | c.921T>A p.F307L | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.454); catalogued as COSV99519233; called by muse, mutect2, varscan2
- TNRC18 | c.8704G>A p.A2902T | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1177327015, COSV99786933; called by muse, mutect2, varscan2
- TRIL | c.1058G>T p.R353L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as COSV100538962; called by muse, mutect2, varscan2
- TRIO | c.6455A>T p.Q2152L | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100710940; called by muse, mutect2, varscan2
- TSPEAR | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 55/71 reads (77%) | catalogued as rs782159618, COSV100555399; called by muse, mutect2, varscan2
- VIL1 | c.1270G>A p.G424S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99945853; called by muse, mutect2, varscan2
- WDR36 | c.860A>C p.Q287P | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1174316344, COSV101540830; called by muse, mutect2, varscan2
- WDR36 | c.861A>T p.Q287H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV101540831, COSV72411537; called by muse, mutect2, varscan2
- ZNF324B | c.1183A>T p.K395* | Nonsense Mutation (SNP) | VAF 19/83 reads (23%) | catalogued as COSV100351791; called by muse, mutect2, varscan2
- ZNF324B | c.1184A>G p.K395R | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.501); catalogued as COSV100351792; called by muse, mutect2, varscan2
- ZNF560 | c.1213G>C p.G405R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.241); catalogued as COSV100039021; called by muse, mutect2, varscan2
- ZNF81 | c.838G>C p.G280R | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as COSV100096188; called by muse, mutect2, varscan2
- ABCC9 | c.109_110del p.L37Vfs*33 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- ASH1L | c.4843del p.R1615Efs*13 | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | called by mutect2, pindel, varscan2
- ATRX | c.2458_2459del p.E820Ifs*10 | Frame Shift Del (DEL) | VAF 25/57 reads (44%) | called by mutect2, pindel, varscan2
- DALRD3 | c.555_556del p.R185Sfs*12 (on ENST00000341949 / NM_001009996.3; = p.R18Sfs*12 on NM_018114.5) | Frame Shift Del (DEL) | VAF 13/64 reads (20%) | called by pindel, varscan2
- DBF4 | c.1059_1060del p.Y353* | Frame Shift Del (DEL) | VAF 30/58 reads (52%) | called by mutect2, pindel, varscan2
- MACF1 | c.8299_8300del p.D2767* | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by pindel, varscan2
- POC1B-GALNT4 | c.478_480del p.P160del | In Frame Del (DEL) | VAF 10/26 reads (38%) | called by mutect2, pindel, varscan2
- RNF139 | c.245_254del p.Y82Sfs*4 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | called by mutect2, pindel, varscan2
- STX10 | c.362_363del p.E121Dfs*41 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | called by pindel, varscan2
- TRAV34 | c.187C>G p.L63V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- ASXL3 | c.45T>C p.A15= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV99326464; called by muse, mutect2, varscan2
- BAIAP2L1 | c.144A>T p.G48= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV99134816; called by muse, mutect2, varscan2
- CASP8AP2 | c.3096C>G p.P1032= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99387200, COSV99387539; called by muse, mutect2, varscan2
- CDKL5 | c.2019T>G p.S673= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV101184451; called by muse, mutect2, varscan2
- CRPPA | c.846C>G p.S282= (on ENST00000407010 / NM_001368197.1; = p.S232= on NM_001101417.4) | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV101235473; called by muse, mutect2, varscan2
- CYP27A1 | c.222T>G p.V74= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV99298735; called by muse, mutect2, varscan2
- DBH | c.1557C>A p.I519= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV101257175; called by muse, mutect2, varscan2
- DOCK6 | c.2409A>T p.G803= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99371103; called by muse, mutect2, varscan2
- FSCB | c.1665T>A p.A555= | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as COSV100469842; called by muse, mutect2, varscan2
- GPBP1L1 | c.600A>G p.K200= | Silent (SNP) | VAF 45/63 reads (71%) | catalogued as COSV99322728; called by muse, mutect2, varscan2
- GPR158 | c.213G>A p.A71= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs1470468872, COSV100894262; called by muse, mutect2, varscan2
- IGHM | c.1287G>C p.V429= | Silent (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- MXRA5 | c.5502A>T p.S1834= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV54257178; called by muse, mutect2, varscan2
- NXPE4 | c.876T>C p.S292= (on ENST00000375478 / NM_001077639.2; = p.S8= on NM_017678.3) | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV64943534; called by muse, mutect2, varscan2
- OR5AK2 | c.639C>T p.V213= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as rs746780389, COSV58804271; called by muse, mutect2, varscan2
- PCDHB14 | c.1680C>T p.F560= | Silent (SNP) | VAF 51/216 reads (24%) | catalogued as rs1211184066, COSV99505949; called by muse, mutect2, varscan2
- PORCN | c.348C>T p.D116= | Silent (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- TEDC2 | c.804G>T p.G268= | Silent (SNP) | VAF 42/64 reads (66%) | catalogued as COSV99564128; called by muse, mutect2, varscan2
- TMBIM6 | c.711A>G p.K237= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs763273442, COSV99920861; called by muse, mutect2, varscan2
- TNRC6C | c.471A>G p.Q157= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100050639; called by muse, mutect2, varscan2
- UMPS | c.969A>G p.K323= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99229289; called by muse, mutect2, varscan2
- URGCP | c.855G>A p.P285= (on ENST00000453200 / NM_001077663.3; = p.P276= on NM_017920.4) | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs766445999, COSV99787875; called by muse, mutect2, varscan2
- HSP90AB1 | c.*107T>G | 3'UTR (SNP) | VAF 22/97 reads (23%) | catalogued as COSV99241398; called by muse, mutect2, varscan2
- MAGEC3 | c.1729-23T>A | Intron (SNP) | VAF 11/30 reads (37%) | catalogued as COSV100026093; called by muse, mutect2, varscan2
- NR2E1 | c.25+1267A>T | Intron (SNP) | VAF 20/94 reads (21%) | catalogued as COSV100934630; called by muse, mutect2, varscan2
- POLR1E | chr9:37486120 C>G | 5'Flank (SNP) | VAF 29/177 reads (16%) | catalogued as COSV100905431; called by muse, mutect2, varscan2
